Gene-level copy-number profile of tumor specimen TCGA-D5-6541-01A from TCGA case TCGA-D5-6541, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Splenic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 49.4 years (18,029 days).
Specimen TCGA-D5-6541-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.45e20c52-97de-401b-adaf-da7a899bba6f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6541-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d5d2b7b3-d2db-41b0-8ea3-f8d6f19b8966

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5,768; copy number 2: 52,030; copy number 3: 1,755; copy number 4: 39; copy number 5: 46; copy number 6: 91; copy number 7: 44; copy number 11: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6541-01A-11D-1717-01): tumor purity 0.58, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 226 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–5,406,651, 135 genes, copy number 5–11 (broad region; genes not listed).
- chr19:17,009,189–18,522,116, 91 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,384. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
